Gene-level copy-number profile of tumor specimen MP2PRT-PAUNIX-TMP1-A from MP2PRT case MP2PRT-PAUNIX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.7 years (1,709 days).
Specimen MP2PRT-PAUNIX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 42ea1b98-df6d-4354-b41c-b9c1cbc5198b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUNIX-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/5751f08f-24f8-41d7-9e8f-8c06ee6c3cf5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 516; copy number 1: 94; copy number 2: 38,967; copy number 3: 12,473; copy number 4: 6,811; copy number 5: 29.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:42,566,679–42,569,353, 2 genes: BX088651.4, BX088651.1.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–4): TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 29 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:124,501–499,156, 18 genes, copy number 5: ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721.
- chr18:45,788,530–46,266,992, 11 genes, copy number 5: AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25.

Autosomal genes at a single copy (total copy number 1): 94. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
